Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7691, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7691-01A (Primary Tumor).

Tumor: [REDACTED]
Normal: [REDACTED]
Slide: [REDACTED]

Addendum Discussion:

Sections demonstrate benign cerebellum with degenerative changes including neuronal loss and gliosis. There is moderately cellular neoplasm composed of cells that resemble modestly atypical fibrillary astrocytes. In general, the tumor appears to have an expanded interface with the adjacent cerebellum. Scattered Rosenthal fibers are present, primarily at the periphery of the tumor. The tumor has a solid growth pattern. Vascular hyalinization is seen and there are numerous microcalcifications. In some areas the calcifications predominate over the tumor cells. No atypical ganglion cells are seen and no eosinophilic granular bodies are noted. Perivascular pseudo rosettes are not noted.

Diagnosis:

CP Angle/Cerebellar Tumor

Well differentiated Astrocytoma (Grade 2)

Source: NCI Genomic Data Commons file 7b473c03-8cc6-4f0f-afba-270073b9dc1d (TCGA-HT-7691.F6B38096-6209-4C37-A545-B4D1643DCC58.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).